Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A924, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A924-01A (Primary Tumor).

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

“I-)Product of total gastrectomy:

- Moderately differentiated tubular adenocarcinoma (Lauren intestinal type), in antropyloric region, largest size: 5.0x4.9cm.
- Tumor invades serosa and non peritonized fat tissue from gastric lesser curvature.
- Non-neoplastic mucosa with inactive superficial chronic gastritis.
- Angiolymphatic and perineural invasion: not observed.
- Surgical margins: uninvolved by neoplasia.

II-)Omentum:

- Uninvolved by neoplasia.

III-)Hepatogastric ligament:

- Uninvolved by neoplasia.

IV-) Esophageal margin:

- Uninvolved by neoplasia.

V-)Lymphadenectomy according to standardization:

- Right paracardic: uninvolved by neoplasia (0/1).
Left paracardic: fat tissue without specific features.
Lesser curvature: uninvolved by neoplasia (0/5).
Left gastroepiploic vessels: uninvolved by neoplasia (0/2).
Right gastroepiploic vessels: uninvolved by neoplasia (0/3).
Suprapyloric: absence of lymph nodes in this specimen.
Infrapyloric: uninvolved by neoplasia (0/5).
Left gastric artery: uninvolved by neoplasia (0/7).
Anterior hepatic artery: uninvolved by neoplasia (0/2)
Celiac trunk: uninvolved by neoplasia (0/2).
Hepatoduodenal ligament: fibrous and fat tissue without specific features.”

Series	hw 11/5/13	Yes	No
Discipline			☒
Primary Discipline			☒
Secondary Discipline			☒
Subject Specialty			☒
Mathematics			☒
Physics			☒
Chemistry			☒
Earth Sciences			☒
Life Sciences			☒
Health Sciences			☒
Other			☒
Other (Specify)	DISQUALIFIED		

Source: NCI Genomic Data Commons file 75311ba9-d879-49aa-b4c9-9e77521d6d8d (TCGA-VQ-A924.CA6148BD-8C92-46A0-A96C-92AE32E254B9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).